Somatic mutation profile of tumor specimen TCGA-FI-A3PV-01A (aliquot TCGA-FI-A3PV-01A-11D-A228-09) from TCGA case TCGA-FI-A3PV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: High Grade; Age at diagnosis: 68.2 years (24,898 days).
Specimen TCGA-FI-A3PV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f77fa61-9e5c-495c-9533-44dad0205189.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FI-A3PV-10A (Blood Derived Normal), aliquot TCGA-FI-A3PV-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d7fa4ed-c237-41c7-855c-1c96097197ac

The open-access MAF lists 69 somatic variants for this specimen: 53 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 12, Splice Site 3, Nonsense Mutation 3, 5'UTR 2, Frame Shift Del 1, Nonstop Mutation 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 14/25 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.448C>G p.Q150E | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as COSV100735780; called by muse, mutect2
- AHCTF1 | c.2702T>G p.M901R (on ENST00000366508; = p.M875R on NM_015446.5) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100403695; called by muse, mutect2, varscan2
- AK3 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100729470, COSV63346252; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.6028C>G p.Q2010E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.075); catalogued as COSV51859849; called by muse, mutect2
- C14orf180 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV100118763, COSV59556818; called by muse, mutect2
- C1RL | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99864692; called by muse, mutect2, varscan2
- CCDC170 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99498430; called by muse, mutect2, varscan2
- CCDC170 | c.350C>G p.T117S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV99498431; called by muse, mutect2, varscan2
- CDKL5 | c.2255G>C p.R752T | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV101184320; called by muse, mutect2, varscan2
- CNTN3 | c.964C>G p.Q322E | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as COSV99724447; called by muse, mutect2, varscan2
- CTSF | c.1016C>G p.S339C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); catalogued as COSV100074275; called by muse, mutect2, varscan2
- DCBLD1 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780427862, COSV51646948; called by muse, mutect2, varscan2
- DDX54 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs760254839, COSV100013883; called by muse, mutect2, varscan2
- DONSON | c.1218C>G p.I406M | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV99278406; called by muse, mutect2, varscan2
- DPP4 | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100858874; called by muse, mutect2
- ENY2 | c.298A>G p.S100G | Missense Mutation (SNP) | VAF 70/90 reads (78%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100373805; called by muse, mutect2, varscan2
- EOGT | c.427T>A p.S143T | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.539); catalogued as COSV99808870; called by muse, mutect2, varscan2
- ERICH3 | c.2977C>T p.R993C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as rs1479259262, COSV100444364, COSV58605573; called by muse, mutect2, varscan2
- FAM200A | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV101282728; called by muse, mutect2
- FUOM | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.072); catalogued as rs775562649, COSV53369459; called by muse, mutect2, varscan2
- IRF4 | c.1151C>G p.T384S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.155); catalogued as COSV66704818; called by muse, mutect2, varscan2
- KIF15 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100392873; called by muse, mutect2, varscan2
- KPNA6 | c.47G>C p.S16T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.102); catalogued as COSV101012508; called by muse, varscan2
- LAMC3 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373592073, COSV100736015; called by muse, mutect2, varscan2
- N4BP2 | c.3651G>T p.M1217I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99788705; called by muse, mutect2
- NADSYN1 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as rs372454516, COSV100034749, COSV100034781; called by muse, mutect2, varscan2
- NCEH1 | c.964G>T p.V322F (on ENST00000538775; = p.V282F on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs755932915, COSV99860131; called by muse, mutect2, varscan2
- OTOGL | c.6953G>A p.R2318H (on ENST00000547103; = p.R2309H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756670112, COSV100087245; called by muse, mutect2, varscan2
- PDLIM5 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs903453897, COSV58747169; called by muse, mutect2
- PFKFB3 | c.498+1G>A p.X166_splice | Splice Site (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100432037; called by muse, mutect2, varscan2
- PIGO | c.2206G>A p.V736I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.076); catalogued as COSV99956672; called by muse, mutect2, varscan2
- PIK3CD | c.1217C>G p.S406C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100740176; called by muse, mutect2, varscan2
- PRH2 | c.65-1G>A p.X22_splice | Splice Site (SNP) | VAF 11/38 reads (29%) | catalogued as COSV101113308, COSV67171739; called by muse, mutect2, varscan2
- PROS1 | c.1365G>C p.L455F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.801); catalogued as COSV101260491; called by muse, mutect2
- RIMS1 | c.3532G>A p.G1178S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99326949; called by muse, mutect2, varscan2
- RNF13 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.205); catalogued as rs781271591, COSV53522601; called by muse, mutect2, varscan2
- RPS3 | c.350+2T>C p.X117_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99584380; called by muse, mutect2, varscan2
- RYR2 | c.905C>G p.T302R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100770264; called by muse, mutect2, varscan2
- SLC16A14 | c.1018A>G p.I340V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.362); catalogued as COSV99725559; called by muse, mutect2, varscan2
- SMARCA4 | c.1888G>A p.G630S | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100758532; called by muse, mutect2, varscan2
- SYNE1 | c.17134G>T p.A5712S (on ENST00000367255 / NM_182961.4; = p.A5641S on NM_033071.3) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99564426; called by muse, mutect2, varscan2
- TBC1D32 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as rs372012861; called by muse, mutect2, varscan2
- TMEM187 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs782576612, COSV100890167; called by muse, mutect2, varscan2
- TSPAN9 | c.96C>G p.I32M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99170871; called by muse, mutect2, varscan2
- USP38 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761852268, COSV61025717; called by muse, mutect2, varscan2
- VPS8 | c.4286G>C p.*1429Sext*1 (on ENST00000625842 / NM_001349294.1; = p.*1427Sext*1 on NM_015303.3 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99802171; called by muse, mutect2, varscan2
- WARS1 | c.268G>T p.V90L | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.402); catalogued as COSV100690178; called by muse, mutect2, varscan2
- WHAMM | c.1444C>G p.L482V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1237850589, COSV99724910; called by muse, mutect2, varscan2
- ZNF175 | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99219500; called by muse, mutect2, varscan2
- ZNF534 | c.327G>T p.L109F (on ENST00000332323 / NM_001143939.3; = p.L96F on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.855); catalogued as COSV56514068, COSV99989793, COSV99990209; called by muse, mutect2, varscan2
- SUCLG2 | c.933del p.L312Sfs*26 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- TRGV3 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ANAPC1 | c.5109G>A p.A1703= | Silent (SNP) | VAF 22/207 reads (11%) | catalogued as rs373638147, COSV100594783; called by muse, mutect2, varscan2
- APEH | c.735C>T p.S245= | Silent (SNP) | VAF 46/107 reads (43%) | catalogued as COSV99608487; called by muse, mutect2, varscan2
- ARHGAP11A | c.2796G>A p.R932= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- C9orf64 | c.189C>T p.A63= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100123572; called by mutect2, varscan2
- CD101 | c.993T>G p.A331= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV99869668; called by muse, mutect2, varscan2
- CDIPT | c.39C>A p.L13= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV54889412, COSV99570196; called by muse, mutect2, varscan2
- DMXL1 | c.1146A>G p.E382= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100223973; called by muse, mutect2, varscan2
- EIF2D | c.19C>A p.R7= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as COSV99662787; called by muse, mutect2, varscan2
- POM121L12 | c.762C>A p.S254= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV101374918, COSV68693184, COSV68693801; called by muse, mutect2, varscan2
- VNN1 | c.1542G>A p.*514= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100907720; called by muse, mutect2, varscan2
- VPS35 | c.2265G>A p.P755= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV54477855; called by muse, mutect2, varscan2
- ZNF44 | c.219G>A p.Q73= (on ENST00000356109 / NM_001164276.2; = p.Q25= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV100633570, COSV61135897; called by muse, mutect2, varscan2
- AMACR | c.739+1134C>A | Intron (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100163049; called by muse, mutect2, varscan2
- GORAB | c.-1G>A | 5'UTR (SNP) | VAF 75/164 reads (46%) | catalogued as CX086060, COSV100883768, COSV63026179; called by muse, mutect2, varscan2
- SSX9P | n.190C>T | RNA (SNP) | VAF 47/179 reads (26%) | called by muse, mutect2, varscan2
- SWI5 | c.-23G>T | 5'UTR (SNP) | VAF 17/19 reads (89%) | catalogued as COSV100199660; called by muse, mutect2, varscan2
